Somatic mutation profile of tumor specimen 28d0abdb-f682-4bd3-9425-a9c508 (aliquot 28d0abdb-f682-4bd3-9425-a9c508_D6) from CPTAC case 17OV018, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 28d0abdb-f682-4bd3-9425-a9c508: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0266de22-d4b5-41cc-bae4-1a7b4a86be04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 4fb7c54a-fefd-4a43-9dcc-f59e89 (Blood Derived Normal), aliquot 4fb7c54a-fefd-4a43-9dcc-f59e89_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da8e6ac8-7880-4da8-b86f-5b1378af1b13

The open-access MAF lists 54 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 10, Intron 5, Frame Shift Del 3, 3'UTR 2, Splice Region 2, 5'UTR 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF1 | c.3335G>T p.S1112I | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV57122738; called by muse, mutect2, varscan2
- AGFG1 | c.1321G>A p.G441S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV59510973; called by muse, mutect2, varscan2
- CTNND2 | c.1125C>G p.H375Q | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.105); catalogued as COSV58894110; called by muse, mutect2, varscan2
- FOXRED1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 117/551 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745954163, COSV55006457; called by muse, mutect2, varscan2
- GAS2L1 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768722703, COSV53330674; called by muse, mutect2, varscan2
- KDM4B | c.432C>T p.D144= | Splice Region (SNP) | VAF 28/75 reads (37%) | catalogued as rs140063768; called by muse, mutect2, varscan2
- MISP3 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.514); catalogued as rs529384554; called by muse, mutect2, varscan2
- MYO5C | c.4969C>T p.R1657C | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs768433487, COSV99953507; called by muse, mutect2, varscan2
- NAPRT | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 222/332 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1185252109; called by muse, mutect2, varscan2
- NOX5 | c.979G>T p.V327L | Missense Mutation (SNP) | VAF 37/413 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV99533598; called by muse, mutect2
- OR51E2 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 80/327 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201184158, COSV67808196; called by muse, mutect2, varscan2
- OR56A1 | c.739C>G p.H247D | Missense Mutation (SNP) | VAF 62/246 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100360423, COSV100360484; called by muse, mutect2, varscan2
- PCDH7 | c.2599G>C p.G867R | Missense Mutation (SNP) | VAF 80/285 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62343477; called by muse, mutect2, varscan2
- PHYHIPL | c.595C>A p.R199= | Splice Region (SNP) | VAF 3/46 reads (7%) | catalogued as COSV65848507; called by muse, mutect2
- PLD1 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 80/165 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as rs771670632, COSV60565942; called by muse, mutect2, varscan2
- SEMA5B | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778251817, COSV52095129, COSV99533431; called by muse, mutect2, varscan2
- TP53 | c.365_366del p.V122Dfs*26 | Frame Shift Del (DEL) | VAF 27/83 reads (33%) | catalogued as rs587780067; called by pindel, varscan2
- TPSD1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs141781532; called by muse, mutect2, varscan2
- ZFHX3 | c.10234A>G p.K3412E | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as rs769933613; called by muse, mutect2, varscan2
- AGPAT3 | c.149A>G p.N50S | Missense Mutation (SNP) | VAF 151/601 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ATG4C | c.1298C>T p.T433I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.024); called by mutect2, varscan2
- CPEB3 | c.831del p.V278Wfs*23 | Frame Shift Del (DEL) | VAF 146/364 reads (40%) | called by mutect2, pindel, varscan2
- DPP10 | c.488A>T p.H163L | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- F13B | c.705T>A p.D235E | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GLYATL3 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 128/667 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAP3 | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LSR | c.1468del p.R490Gfs*106 (on ENST00000361790; = p.R471Gfs*106 on NM_015925.6) | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | called by mutect2, pindel, varscan2
- LY6H | c.357C>G p.S119R | Missense Mutation (SNP) | VAF 30/395 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- MRFAP1 | c.230G>C p.S77T | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- PAPPA | c.1664G>T p.G555V | Missense Mutation (SNP) | VAF 173/295 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPS23 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- SPATA16 | c.1437T>G p.N479K | Missense Mutation (SNP) | VAF 41/414 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- SYPL2 | c.533T>C p.V178A | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- WIZ | c.2226G>C p.M742I | Missense Mutation (SNP) | VAF 106/165 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- FNDC1 | c.2232G>T p.G744= | Silent (SNP) | VAF 63/258 reads (24%) | called by muse, mutect2, varscan2
- GIMAP7 | c.81C>T p.T27= | Silent (SNP) | VAF 66/209 reads (32%) | called by muse, mutect2, varscan2
- OR51M1 | c.540C>T p.Y180= | Silent (SNP) | VAF 161/612 reads (26%) | catalogued as rs1225159861; called by muse, mutect2, varscan2
- POU5F1B | c.291C>T p.S97= | Silent (SNP) | VAF 33/912 reads (4%) | called by muse, mutect2
- PRR23A | c.528C>T p.A176= | Silent (SNP) | VAF 94/307 reads (31%) | catalogued as rs1378540979; called by muse, mutect2, varscan2
- SPEG | c.8124G>A p.T2708= | Silent (SNP) | VAF 65/312 reads (21%) | catalogued as rs374304716; called by muse, mutect2, varscan2
- TENM2 | c.342C>T p.D114= | Silent (SNP) | VAF 34/188 reads (18%) | catalogued as COSV72855268; called by muse, mutect2, varscan2
- TMEM82 | c.309C>T p.A103= | Silent (SNP) | VAF 42/196 reads (21%) | catalogued as rs527631817; called by muse, mutect2, varscan2
- TRAF3 | c.388C>T p.L130= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as rs768019749; called by muse, mutect2, varscan2
- UNC13A | c.828G>A p.L276= | Silent (SNP) | VAF 45/290 reads (16%) | called by muse, mutect2, varscan2
- ADAM9 | c.*929C>A | 3'UTR (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- COL4A3 | c.2657-15A>C | Intron (SNP) | VAF 40/235 reads (17%) | catalogued as rs751284662; called by muse, mutect2, varscan2
- FBXL19 | chr16:30923059 T>C | 5'Flank (SNP) | VAF 57/267 reads (21%) | called by muse, mutect2, varscan2
- GPNMB | c.-14C>T | 5'UTR (SNP) | VAF 58/261 reads (22%) | catalogued as COSV99326480; called by muse, mutect2, varscan2
- MLN | c.*7C>A | 3'UTR (SNP) | VAF 28/155 reads (18%) | called by muse, mutect2, varscan2
- NUDT22 | c.480+62_480+65del | Intron (DEL) | VAF 21/197 reads (11%) | called by mutect2, pindel, varscan2
- OR2A13P | n.890A>C | RNA (SNP) | VAF 80/172 reads (47%) | called by muse, mutect2, varscan2
- RUSC1 | c.1358-288A>G | Intron (SNP) | VAF 7/68 reads (10%) | catalogued as rs746253673; called by muse, mutect2, varscan2
- ZNF346 | c.175+302del | Intron (DEL) | VAF 29/116 reads (25%) | called by mutect2, pindel, varscan2
- ZNF605 | c.15+10C>A | Intron (SNP) | VAF 56/249 reads (22%) | called by muse, mutect2, varscan2
